Somatic mutation profile of tumor specimen TCGA-S7-A7WO-01A (aliquot TCGA-S7-A7WO-01A-11D-A35I-08) from TCGA case TCGA-S7-A7WO, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 77.0 years (28,114 days).
Specimen TCGA-S7-A7WO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f6e6e46-cdbd-4ef5-abc8-4b0511adf4e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S7-A7WO-10A (Blood Derived Normal), aliquot TCGA-S7-A7WO-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58948c57-3d77-4010-9ff1-2221a1cea78a

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SIGLEC9 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2
- SNTG2 | c.831G>A p.R277= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1041337153; called by muse, mutect2, varscan2
